Somatic mutation profile of tumor specimen MBCProject_0454_T1_WES (aliquot MBCProject_0454_T1_WES_1) from CMI case MBCProject_0454, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 33.5 years (12,228 days).
Specimen MBCProject_0454_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5703def-3c46-4122-b825-1926b6837f19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0454_SALIVA (Saliva), aliquot MBCProject_0454_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/103cc7cc-1961-443d-954b-a09eb6c999b0

The open-access MAF lists 46 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Intron 6, Splice Region 2, Splice Site 1, 5'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62491803, COSV62494609; called by muse, mutect2, varscan2
- ATP6V0D2 | c.836A>C p.E279A | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV53415693; called by muse, mutect2, varscan2
- CDH3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200463078, COSV50561248; called by muse, mutect2, varscan2
- INF2 | c.3199G>A p.G1067S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1328349434; called by muse, mutect2, varscan2
- PARK7 | c.253-2A>G p.X85_splice | Splice Site (SNP) | VAF 70/566 reads (12%) | catalogued as COSV58579590; called by muse, mutect2, varscan2
- PCDHA5 | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.093); catalogued as rs782065651; called by muse, mutect2, varscan2
- PCLO | c.5541A>T p.E1847D | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV61626041; called by muse, mutect2, varscan2
- RPS6KA2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 15/301 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs1470862955, COSV99690452; called by muse, mutect2
- TRPM5 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as rs780521772, COSV50153310, COSV50157216; called by muse, mutect2, varscan2
- BFAR | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 104/494 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOLA3 | c.54+6C>A | Splice Region (SNP) | VAF 115/465 reads (25%) | called by muse, mutect2, varscan2
- CACNA1D | c.3315G>T p.A1105= (on ENST00000350061 / NM_001128840.3; = p.A1125= on NM_000720.4) | Splice Region (SNP) | VAF 41/367 reads (11%) | called by muse, mutect2, varscan2
- CCDC186 | c.2558A>T p.N853I | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CELF2 | c.423G>T p.K141N (on ENST00000416382 / NM_001025077.3; = p.K148N on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GFY | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- MAP4K1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 147/495 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PDGFD | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- PLXNA2 | c.2953G>C p.V985L | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PRR9 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- QRICH1 | c.833G>T p.S278I | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- RANBP2 | c.5531A>C p.N1844T | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- SLC15A1 | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D9 | c.1632C>A p.D544E | Missense Mutation (SNP) | VAF 141/442 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNCX | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ZNF761 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, varscan2
- ZNF761 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ABCF1 | c.1734C>T p.A578= (on ENST00000326195 / NM_001025091.2; = p.A540= on NM_001090.3) | Silent (SNP) | VAF 21/95 reads (22%) | called by mutect2, varscan2
- CAMK2B | c.1218C>T p.D406= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs756933665, COSV51662695; called by muse, mutect2, varscan2
- HDAC9 | c.1530G>A p.Q510= | Silent (SNP) | VAF 74/243 reads (30%) | catalogued as rs745581313; called by muse, mutect2, varscan2
- ITPR1 | c.7590G>A p.T2530= (on ENST00000354582; = p.T2475= on NM_002222.7) | Silent (SNP) | VAF 96/374 reads (26%) | catalogued as rs146028585; called by muse, mutect2, varscan2
- KRT5 | c.1420C>T p.L474= | Silent (SNP) | VAF 9/234 reads (4%) | called by muse, mutect2
- LYSMD4 | c.147G>T p.R49= (on ENST00000409796 / NM_001284417.2; = p.G20V on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/423 reads (13%) | called by muse, mutect2, varscan2
- OR7D4 | c.99C>T p.S33= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- SLC17A4 | c.216C>T p.S72= | Silent (SNP) | VAF 97/293 reads (33%) | catalogued as rs1266856407; called by muse, mutect2, varscan2
- SLC22A4 | c.1173A>G p.L391= | Silent (SNP) | VAF 96/376 reads (26%) | called by muse, mutect2, varscan2
- TENM2 | c.7767C>A p.A2589= (on ENST00000518659 / NM_001122679.2; = p.A2350= on NM_001080428.3) | Silent (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- TMEM26 | c.1038T>C p.S346= | Silent (SNP) | VAF 51/212 reads (24%) | called by muse, mutect2, varscan2
- ALAS2 | c.-15-1832C>T | Intron (SNP) | VAF 82/171 reads (48%) | called by muse, mutect2, varscan2
- ALAS2 | c.-15-1833G>A | Intron (SNP) | VAF 82/169 reads (49%) | called by muse, mutect2, varscan2
- DAO | chr12:108879824 G>C | 5'Flank (SNP) | VAF 21/144 reads (15%) | catalogued as COSV57322574; called by muse, mutect2, varscan2
- GLYATL1 | n.207G>A | RNA (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- KCNH2 | c.1945+12C>T | Intron (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- NAP1L1 | c.917-28A>C | Intron (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.132-16742C>T | Intron (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- TBXT | c.-11C>T | 5'UTR (SNP) | VAF 7/108 reads (6%) | catalogued as rs1198430776; called by muse, mutect2
- TNFAIP2 | c.1423-40C>T | Intron (SNP) | VAF 86/277 reads (31%) | called by muse, mutect2, varscan2
